Somatic mutation profile of tumor specimen TCGA-G7-7501-01A (aliquot TCGA-G7-7501-01A-11D-2201-08) from TCGA case TCGA-G7-7501, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 55.2 years (20,165 days).
Specimen TCGA-G7-7501-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4ee5b3b8-f2d5-4bcc-8cb7-e5b5a0d03d35.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G7-7501-10A (Blood Derived Normal), aliquot TCGA-G7-7501-10A-01D-2201-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bf4d786b-e3f5-4cb6-844d-f9491f73ee54

The open-access MAF lists 37 somatic variants for this specimen: 29 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 23, Silent 8, Nonsense Mutation 4, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC098582.1 | c.691G>T p.E231* | Nonsense Mutation (SNP) | VAF 24/34 reads (71%) | catalogued as COSV52026216; called by muse, mutect2, varscan2
- ARAP1 | c.3496A>G p.S1166G (on ENST00000393609 / NM_001040118.2; = p.S921G on NM_015242.4) | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as rs752718628, COSV61995915; called by muse, mutect2, varscan2
- CAPZA3 | c.833T>A p.L278Q | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.802); catalogued as COSV56859875; called by muse, mutect2, varscan2
- CCT8L2 | c.59G>A p.R20K | Missense Mutation (SNP) | VAF 23/29 reads (79%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs761693167, COSV100742591, COSV63464126; called by muse, mutect2, varscan2
- CLUH | c.1207G>A p.G403S (on ENST00000435359; = p.G441S on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1373639535, COSV70930218; called by muse, mutect2, varscan2
- DCAF6 | c.808G>A p.V270I | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as rs1013962018, COSV56586763; called by muse, mutect2, varscan2
- DNASE1L3 | c.757A>G p.S253G | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as COSV59157735; called by muse, mutect2, varscan2
- HSPE1-MOB4 | c.152C>G p.S51W | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.376); catalogued as COSV52098312, COSV52100395; called by muse, mutect2, varscan2
- KCNK5 | c.832C>T p.Q278* | Nonsense Mutation (SNP) | VAF 47/147 reads (32%) | catalogued as COSV63989546; called by muse, mutect2, varscan2
- KRT75 | c.449G>A p.R150H | Missense Mutation (SNP) | VAF 56/143 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs201256120, COSV52875731; called by muse, mutect2, varscan2
- MCF2 | c.1825G>A p.A609T | Missense Mutation (SNP) | VAF 62/201 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.06); catalogued as rs202133857, COSV58496604, COSV58496703; called by muse, mutect2, varscan2
- MORF4L1 | c.664T>C p.Y222H (on ENST00000331268 / NM_206839.2; = p.Y183H on NM_006791.4) | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV58705991; called by muse, mutect2, varscan2
- MTUS2 | c.1516G>A p.V506I | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as COSV70924507; called by muse, mutect2, varscan2
- MYOZ3 | c.94G>A p.V32M | Missense Mutation (SNP) | VAF 16/24 reads (67%) | SIFT deleterious (0.03); PolyPhen benign (0.371); catalogued as rs370373786; called by muse, mutect2, varscan2
- NAPB | c.532T>C p.Y178H | Missense Mutation (SNP) | VAF 48/106 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV65465507; called by muse, mutect2, varscan2
- NPTX1 | c.1256G>T p.G419V | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60776977; called by muse, mutect2
- PLEKHB2 | c.475G>C p.V159L (on ENST00000409279; = p.V158L on NM_017958.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.03); catalogued as rs143964327; called by muse, mutect2, varscan2
- PLEKHG2 | c.2779C>G p.L927V | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV52691291; called by muse, mutect2, varscan2
- PTPRZ1 | c.5507A>T p.K1836I | Missense Mutation (SNP) | VAF 33/62 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.865); catalogued as COSV66447450; called by muse, mutect2, varscan2
- RBBP6 | c.3871A>C p.T1291P | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV60509165; called by muse, mutect2, varscan2
- RIPK4 | c.1927G>T p.V643L (on ENST00000352483; = p.V595L on NM_020639.3) | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.519); catalogued as COSV60192187; called by muse, mutect2, varscan2
- SLC8A2 | c.134G>A p.G45E | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV52643552; called by muse, mutect2, varscan2
- TTN | c.29347G>T p.E9783* (on ENST00000591111; = p.E8856* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 42/83 reads (51%) | catalogued as COSV60411137; called by muse, mutect2, varscan2
- TXNDC16 | c.1952C>G p.T651R | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV55988200; called by muse, mutect2
- ZNF45 | c.1354G>A p.G452S | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.404); catalogued as COSV54194999; called by muse, mutect2, varscan2
- ZNF700 | c.1289C>T p.A430V | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (0.49); PolyPhen benign (0.036); catalogued as COSV54315885; called by muse, mutect2, varscan2
- HLA-DPB1 | c.266del p.N89Tfs*28 | Frame Shift Del (DEL) | VAF 12/52 reads (23%) | called by mutect2, pindel
- LAMTOR4 | c.3+1dup | Frame Shift Ins (INS) | VAF 20/86 reads (23%) | called by mutect2, pindel, varscan2
- TRPC5 | c.1626_1628del p.Y542_E543delins* | Nonsense Mutation (DEL) | VAF 56/125 reads (45%) | called by mutect2, pindel, varscan2
- CGAS | c.1449T>C p.Y483= | Silent (SNP) | VAF 17/38 reads (45%) | catalogued as COSV64809149; called by muse, mutect2, varscan2
- CPED1 | c.102C>G p.T34= | Silent (SNP) | VAF 36/84 reads (43%) | catalogued as COSV100120338, COSV60015555; called by muse, mutect2, varscan2
- FCMR | c.666C>G p.P222= | Silent (SNP) | VAF 24/91 reads (26%) | catalogued as COSV65569870; called by muse, mutect2, varscan2
- INTS3 | c.1866A>G p.L622= | Silent (SNP) | VAF 42/98 reads (43%) | catalogued as COSV59682270; called by muse, mutect2, varscan2
- MLXIP | c.1008C>T p.F336= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as COSV59838488; called by muse, mutect2
- NBEA | c.3432A>C p.T1144= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as rs748920797, COSV59830993; called by muse, mutect2, varscan2
- PIGR | c.1992G>C p.R664= | Silent (SNP) | VAF 30/91 reads (33%) | catalogued as COSV100732660, COSV62905245; called by muse, mutect2, varscan2
- SF3B2 | c.1890C>A p.P630= | Silent (SNP) | VAF 18/35 reads (51%) | catalogued as COSV59430547; called by muse, mutect2, varscan2
